Somatic mutation profile of tumor specimen C3L-02169-01 (aliquot CPT0175660006) from CPTAC case C3L-02169, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 56.8 years (20,732 days).
Specimen C3L-02169-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49b60f75-f612-4546-8ca4-d248e7671610.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02169-31 (Blood Derived Normal), aliquot CPT0175780002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/80df6da8-8660-47f6-9809-1d03bb114b3e

The open-access MAF lists 995 somatic variants for this specimen: 702 protein-altering or splice-affecting, 193 silent, 100 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 606, Silent 193, Nonsense Mutation 52, Intron 35, RNA 26, Splice Site 16, 5'UTR 15, 5'Flank 14, Frame Shift Del 11, Splice Region 8, 3'UTR 7, Frame Shift Ins 5.

Variants (750 of 995; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOB | c.10187C>A p.A3396D | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs730880052; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 10/79 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- RYR2 | c.9688C>A p.Q3230K | Missense Mutation (SNP) | VAF 26/333 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs886037908; ClinVar: likely pathogenic; called by muse, mutect2
- ABI3BP | c.1628C>A p.P543Q | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as COSV52539398; called by muse, mutect2, varscan2
- ACACB | c.4510C>G p.R1504G | Missense Mutation (SNP) | VAF 54/568 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100622215; called by muse, mutect2
- ACSBG1 | c.491G>A p.G164D | Missense Mutation (SNP) | VAF 33/338 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs935476084, COSV51905886; called by muse, mutect2
- ACSM3 | c.687C>G p.I229M | Missense Mutation (SNP) | VAF 22/211 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99184571; called by muse, mutect2, varscan2
- ADAM7 | c.834C>G p.I278M | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.77); catalogued as COSV51542522; called by muse, mutect2
- ADCY10 | c.1370G>T p.G457V | Missense Mutation (SNP) | VAF 14/347 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63240011; called by muse, mutect2
- ADGRB2 | c.3248C>T p.P1083L | Missense Mutation (SNP) | VAF 10/213 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1455738681; called by muse, mutect2
- AFMID | c.351G>T p.Q117H | Missense Mutation (SNP) | VAF 62/542 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV59977809; called by muse, mutect2, varscan2
- AGTR1 | c.832G>C p.D278H | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV62560121; called by muse, mutect2, varscan2
- AMOTL1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 14/151 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV58570956; called by muse, mutect2
- AMOTL2 | c.1152G>A p.M384I | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV51440288; called by muse, mutect2, varscan2
- ANKRD17 | c.4775C>T p.S1592L | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.175); catalogued as rs1560513504; called by muse, mutect2, varscan2
- APLNR | c.1045G>T p.G349W | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.22); catalogued as COSV57241240; called by muse, mutect2, varscan2
- ASAP3 | c.1014G>T p.T338= | Splice Region (SNP) | VAF 22/225 reads (10%) | catalogued as COSV100369597; called by muse, mutect2, varscan2
- ASZ1 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.231); catalogued as COSV52916678; called by muse, mutect2
- ATP1A1 | c.200G>T p.R67L | Missense Mutation (SNP) | VAF 55/327 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.075); catalogued as COSV55192926; called by muse, mutect2, varscan2
- BAMBI | c.615G>T p.K205N | Missense Mutation (SNP) | VAF 35/270 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV65002739; called by muse, mutect2, varscan2
- BCAN | c.697G>T p.G233W | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61257971; called by muse, mutect2, varscan2
- BMPR2 | c.259C>G p.H87D | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.119); catalogued as CM146772; called by muse, mutect2
- C16orf92 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 51/284 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as COSV54227725; called by muse, mutect2, varscan2
- CACNA1E | c.608G>C p.G203A | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100703927; called by muse, mutect2, varscan2
- CASQ2 | c.1014+1G>T p.X338_splice | Splice Site (SNP) | VAF 28/402 reads (7%) | catalogued as CS117807; called by muse, mutect2
- CBLN4 | c.241C>A p.H81N | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as COSV50353815; called by muse, mutect2
- CCDC115 | c.480G>T p.W160C | Missense Mutation (SNP) | VAF 21/317 reads (7%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.929); catalogued as COSV52091610, COSV52092828; called by muse, mutect2
- CCDC172 | c.52G>T p.E18* | Nonsense Mutation (SNP) | VAF 62/433 reads (14%) | catalogued as COSV100319840, COSV60939594; called by muse, mutect2, varscan2
- CCDC90B | c.83C>T p.S28L | Missense Mutation (SNP) | VAF 18/310 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.085); catalogued as rs1266650740, COSV52623421; called by muse, mutect2
- CCM2 | c.748G>T p.D250Y | Missense Mutation (SNP) | VAF 56/522 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.111); catalogued as COSV51848317; called by muse, mutect2, varscan2
- CDH4 | c.2138G>T p.C713F | Missense Mutation (SNP) | VAF 60/530 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as COSV100849061; called by muse, mutect2, varscan2
- CDH8 | c.511C>A p.P171T | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV100180206, COSV54867911; called by muse, mutect2, varscan2
- CDK12 | c.2867G>T p.C956F | Missense Mutation (SNP) | VAF 19/185 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71002875; called by muse, mutect2, varscan2
- CDKL5 | c.2116G>A p.D706N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as COSV101184154; called by muse, mutect2, varscan2
- CEP250 | c.6011C>T p.S2004F | Missense Mutation (SNP) | VAF 66/661 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.173); catalogued as rs1033436914; called by muse, mutect2
- CFAP44 | c.1127A>G p.Y376C | Missense Mutation (SNP) | VAF 24/166 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.227); catalogued as rs370294371; called by muse, mutect2, varscan2
- CGNL1 | c.875G>T p.R292L | Missense Mutation (SNP) | VAF 37/237 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.2); catalogued as COSV55575036; called by muse, mutect2, varscan2
- CHST3 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs1432956077, COSV64150622; called by muse, varscan2
- CLHC1 | c.743G>T p.W248L | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100811471; called by muse, mutect2, varscan2
- CMTR2 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.073); catalogued as COSV100579002; called by muse, mutect2, varscan2
- CNTNAP2 | c.3898G>T p.G1300W | Missense Mutation (SNP) | VAF 71/486 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100667116; called by muse, mutect2, varscan2
- CNTNAP5 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70500888, COSV70520027; called by muse, mutect2, varscan2
- COL11A1 | c.4015G>T p.G1339* | Nonsense Mutation (SNP) | VAF 15/236 reads (6%) | catalogued as COSV62181122; called by muse, mutect2
- COL19A1 | c.1922G>T p.G641V | Missense Mutation (SNP) | VAF 21/210 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100506914; called by muse, mutect2, varscan2
- COL22A1 | c.154G>C p.E52Q | Missense Mutation (SNP) | VAF 12/173 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.833); catalogued as COSV57337842; called by muse, mutect2
- COL25A1 | c.1616C>A p.P539Q | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.997); catalogued as rs774140956; called by muse, mutect2, varscan2
- COL3A1 | c.3437G>T p.G1146V | Missense Mutation (SNP) | VAF 65/499 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1412726, COSV58594133; called by muse, mutect2, varscan2
- COL6A3 | c.4624C>A p.Q1542K | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55115277; called by muse, mutect2
- CPEB2 | c.1265C>T p.S422L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.03); catalogued as rs1052878736; called by muse, mutect2, varscan2
- CRB3 | c.292G>A p.E98K | Missense Mutation (SNP) | VAF 106/553 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs751295212, COSV100375418; called by muse, mutect2, varscan2
- CSMD3 | c.6875G>A p.G2292D (on ENST00000297405 / NM_001363185.1; = p.G2188D on NM_052900.3) | Missense Mutation (SNP) | VAF 6/154 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs951593485, COSV99828991, COSV99840533; called by muse, mutect2
- CSMD3 | c.3526G>T p.E1176* (on ENST00000297405 / NM_001363185.1; = p.E1072* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 29/181 reads (16%) | catalogued as COSV52162861; called by muse, mutect2, varscan2
- CSMD3 | c.1694C>A p.P565Q (on ENST00000297405 / NM_001363185.1; = p.P461Q on NM_052900.3) | Missense Mutation (SNP) | VAF 29/206 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV52246013; called by muse, mutect2, varscan2
- CUBN | c.10033-1G>A p.X3345_splice | Splice Site (SNP) | VAF 31/190 reads (16%) | catalogued as rs765616473; called by muse, mutect2, varscan2
- CUBN | c.3833G>T p.C1278F | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100913794; called by muse, mutect2
- DCAF4L2 | c.77C>A p.P26H | Missense Mutation (SNP) | VAF 24/406 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100151132; called by muse, mutect2
- DCDC1 | c.3518A>T p.Q1173L (on ENST00000597505 / NM_001367979.1; = p.Q280L on NM_020869.3) | Missense Mutation (SNP) | VAF 108/536 reads (20%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.785); catalogued as rs1263168462; called by muse, mutect2, varscan2
- DDX20 | c.1991C>T p.S664F | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100862048; called by muse, mutect2
- DGKB | c.640G>A p.V214M | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs982542800, COSV51796521; called by muse, mutect2
- DGKI | c.3118G>C p.D1040H | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV55950781; called by muse, mutect2, varscan2
- DIPK2B | c.1237C>A p.L413M | Missense Mutation (SNP) | VAF 49/168 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.726); catalogued as COSV67641149; called by muse, mutect2, varscan2
- DLGAP2 | c.503C>A p.S168* | Nonsense Mutation (SNP) | VAF 12/375 reads (3%) | catalogued as COSV70103926; called by muse, mutect2
- DLGAP2 | c.781G>C p.G261R | Missense Mutation (SNP) | VAF 26/402 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as rs767334645; called by muse, mutect2
- DNAJC13 | c.5200G>A p.A1734T | Missense Mutation (SNP) | VAF 38/347 reads (11%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs538703638, COSV99607004; called by muse, mutect2, varscan2
- DOCK10 | c.364G>T p.V122L | Missense Mutation (SNP) | VAF 5/84 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.331); catalogued as rs1335164241; called by muse, mutect2
- DOCK8 | c.2531G>T p.R844M | Missense Mutation (SNP) | VAF 26/442 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV101210015; called by muse, mutect2
- DSCAM | c.3014G>A p.W1005* | Nonsense Mutation (SNP) | VAF 19/270 reads (7%) | catalogued as COSV68021153, COSV68028943; called by muse, mutect2
- DUSP21 | c.305C>A p.T102K | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV59133479; called by muse, mutect2, varscan2
- DUSP26 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 35/591 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56361759; called by muse, mutect2
- EDIL3 | c.649C>A p.Q217K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV56885612; called by muse, mutect2, varscan2
- ELL | c.601G>T p.G201W | Missense Mutation (SNP) | VAF 79/423 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV53212106; called by muse, mutect2, varscan2
- ELOVL3 | c.209G>T p.W70L | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1564989631; called by muse, mutect2
- ELOVL4 | c.810C>A p.Y270* | Nonsense Mutation (SNP) | VAF 26/288 reads (9%) | catalogued as CM045143; called by muse, mutect2
- ERICH3 | c.4592A>G p.*1531Wext*31 | Nonstop Mutation (SNP) | VAF 11/87 reads (13%) | catalogued as rs746770458; called by mutect2, varscan2
- EXOC6B | c.280-1G>T p.X94_splice | Splice Site (SNP) | VAF 8/70 reads (11%) | catalogued as COSV99726398; called by muse, mutect2
- FAM110A | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 24/180 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV99856720; called by muse, mutect2, varscan2
- FAM126B | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 22/359 reads (6%) | SIFT tolerated (1); PolyPhen probably damaging (0.966); catalogued as COSV53773474; called by muse, mutect2
- FAM178B | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 42/349 reads (12%) | SIFT tolerated (0.28); PolyPhen benign (0.385); catalogued as rs1031086863; called by muse, mutect2, varscan2
- FAM71C | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as rs1306154451; called by muse, mutect2, varscan2
- FAM83B | c.974G>T p.R325I | Missense Mutation (SNP) | VAF 18/165 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.362); catalogued as COSV60922464; called by muse, varscan2
- FOXS1 | c.35C>A p.P12H | Missense Mutation (SNP) | VAF 86/353 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54069155; called by muse, varscan2
- FRMPD4 | c.43C>G p.H15D | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66216819; called by muse, mutect2, varscan2
- GABRG3 | c.277C>A p.Q93K | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as COSV99075870; called by muse, mutect2
- GCDH | c.590A>G p.Y197C | Missense Mutation (SNP) | VAF 107/537 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV53366762; called by muse, mutect2, varscan2
- GGCX | c.208C>G p.L70V | Missense Mutation (SNP) | VAF 19/392 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.673); catalogued as COSV104374468; called by muse, mutect2
- GIGYF2 | c.3722C>T p.S1241L | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs749572466; called by muse, mutect2
- GIMAP8 | c.26C>A p.S9Y | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.459); catalogued as COSV56232715; called by muse, mutect2
- GLB1L3 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 13/192 reads (7%) | catalogued as rs1471552381; called by muse, mutect2
- GP6 | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 76/585 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.024); catalogued as rs575231122, COSV100117568; called by muse, mutect2, varscan2
- GPR137C | c.850G>T p.D284Y | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs757031023, COSV58704474; called by muse, mutect2, varscan2
- GRIN2B | c.2761G>T p.A921S | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.613); catalogued as COSV101663209; called by muse, mutect2
- GRM6 | c.1248C>A p.H416Q | Missense Mutation (SNP) | VAF 162/643 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV51448595; called by muse, mutect2, varscan2
- GRXCR1 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 32/288 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); catalogued as rs142351714, COSV67670862, COSV67672841; called by muse, mutect2, varscan2
- GTSE1 | c.719C>A p.A240E | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV104437368; called by muse, mutect2
- H2BC9 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 62/554 reads (11%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.034); catalogued as rs1561760033, COSV55099491, COSV55099681; called by muse, mutect2, varscan2
- HOXC12 | c.727C>A p.R243S | Missense Mutation (SNP) | VAF 33/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1233768677; called by muse, mutect2, varscan2
- ICE1 | c.1844C>G p.S615* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV56830962; called by muse, mutect2, varscan2
- ICE1 | c.6669G>C p.L2223F | Missense Mutation (SNP) | VAF 13/359 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99665886; called by muse, mutect2
- IGHV2-26 | c.261G>T p.R87S | Missense Mutation (SNP) | VAF 26/519 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.276); catalogued as rs782439014; called by muse, mutect2
- IL23R | c.1555G>T p.G519* | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100724877; called by muse, mutect2, varscan2
- KCNA5 | c.55G>A p.G19S | Missense Mutation (SNP) | VAF 36/576 reads (6%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.054); catalogued as rs1204966408; called by muse, mutect2
- KCNC2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 73/637 reads (11%) | catalogued as COSV54362045; called by muse, mutect2, varscan2
- KCNC2 | c.227G>T p.G76V | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.999); catalogued as rs1326421660; called by muse, mutect2
- KCNV1 | c.982C>T p.H328Y | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52086048; called by muse, mutect2
- KIAA1549L | c.1490T>C p.M497T (on ENST00000321505; = p.M794T on NM_012194.3) | Missense Mutation (SNP) | VAF 75/316 reads (24%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as COSV55780481; called by muse, mutect2, varscan2
- KIRREL1 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 23/230 reads (10%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV63291929; called by muse, mutect2
- KLF2 | c.175G>A p.E59K | Missense Mutation (SNP) | VAF 84/393 reads (21%) | SIFT tolerated (0.88); PolyPhen benign (0.089); catalogued as COSV50179568; called by muse, mutect2, varscan2
- KPNA2 | c.333del p.I112* | Frame Shift Del (DEL) | VAF 16/175 reads (9%) | catalogued as COSV100388724; called by mutect2, pindel
- LCE2C | c.250C>G p.R84G | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.001); catalogued as COSV64228585; called by muse, mutect2
- LEPR | c.2084T>A p.V695E | Missense Mutation (SNP) | VAF 24/138 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100756734; called by muse, mutect2, varscan2
- LINGO2 | c.1025C>T p.S342F | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as COSV58064279; called by muse, mutect2
- LOXHD1 | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59672441; called by muse, mutect2
- LPO | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs147244264; called by muse, mutect2, varscan2
- LRIT1 | c.158C>A p.P53H | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV64512208; called by muse, mutect2, varscan2
- LRP1B | c.3574G>T p.G1192* | Nonsense Mutation (SNP) | VAF 16/212 reads (8%) | catalogued as COSV101252376; called by muse, mutect2
- LRRC7 | c.3120G>T p.M1040I (on ENST00000651989 / NM_001370785.2; = p.M1007I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/190 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV50471799; called by muse, mutect2
- MAP3K19 | c.2750C>A p.S917Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV59642998; called by muse, mutect2, varscan2
- MARCHF11 | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs765057383; called by muse, mutect2
- MDGA2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV62100422; called by muse, mutect2, varscan2
- MFAP3L | c.316G>A p.D106N | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.14); catalogued as rs760906723; called by muse, mutect2, varscan2
- MMP17 | c.638C>A p.P213H | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100861963; called by muse, mutect2
- MROH8 | c.13G>C p.E5Q | Missense Mutation (SNP) | VAF 7/142 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.233); catalogued as COSV54125471; called by muse, mutect2
- MTRNR2L7 | c.41G>T p.R14M | Missense Mutation (SNP) | VAF 19/144 reads (13%) | PolyPhen benign (0); catalogued as COSV99075854; called by muse, mutect2, varscan2
- MTSS1 | c.481C>G p.Q161E | Missense Mutation (SNP) | VAF 24/478 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as COSV61498132; called by muse, mutect2
- MTUS2 | c.2101C>A p.P701T | Missense Mutation (SNP) | VAF 17/291 reads (6%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV70924301; called by muse, mutect2
- MUC16 | c.16991T>A p.L5664H | Missense Mutation (SNP) | VAF 67/323 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.476); catalogued as COSV101198329; called by muse, mutect2, varscan2
- MUC17 | c.5480C>T p.T1827I | Missense Mutation (SNP) | VAF 16/160 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.86); catalogued as rs201493125; called by muse, mutect2, varscan2
- MUC5AC | c.637del p.D213Tfs*18 | Frame Shift Del (DEL) | VAF 39/414 reads (9%) | catalogued as COSV100650732; called by mutect2, pindel
- MXRA5 | c.5770G>A p.G1924S | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768537310; called by muse, mutect2, varscan2
- NELFA | c.224C>T p.P75L (on ENST00000542778; = p.P64L on NM_005663.5) | Missense Mutation (SNP) | VAF 35/219 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.092); catalogued as rs1412456344; called by muse, mutect2, varscan2
- NLRP14 | c.380G>T p.R127I | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as COSV55069967; called by muse, mutect2, varscan2
- NOD2 | c.2074G>A p.E692K | Missense Mutation (SNP) | VAF 58/299 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs143782684; called by muse, mutect2, varscan2
- NRAS | c.29G>T p.G10V | Missense Mutation (SNP) | VAF 40/558 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54739076; called by muse, mutect2
- NRG3 | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 25/282 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs1294798567; called by muse, mutect2
- NTRK3 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 65/580 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV58117897; called by muse, mutect2, varscan2
- NTSR1 | c.883G>T p.V295F | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.255); catalogued as COSV100980595; called by muse, mutect2, varscan2
- NUP133 | c.197G>T p.R66L | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.468); catalogued as COSV99066492; called by muse, mutect2
- NUP160 | c.2257G>T p.G753C | Missense Mutation (SNP) | VAF 15/153 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV65855983; called by muse, mutect2
- OR10J3 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.187); catalogued as COSV59954356; called by muse, mutect2
- OR13C4 | c.838G>C p.V280L | Missense Mutation (SNP) | VAF 30/195 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV52928913; called by muse, mutect2, varscan2
- OR1S1 | c.115C>T p.L39F | Missense Mutation (SNP) | VAF 31/286 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.033); catalogued as rs754020440, COSV58706603, COSV58707945; called by muse, mutect2, varscan2
- OR2M3 | c.211C>A p.L71I | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.27); catalogued as COSV101513393; called by muse, mutect2
- OR4A47 | c.281C>A p.S94Y | Missense Mutation (SNP) | VAF 58/335 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.235); catalogued as COSV71444917; called by muse, mutect2, varscan2
- OR4C16 | c.857C>A p.T286K | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs369710100; called by muse, mutect2
- OR51G2 | c.393C>G p.I131M | Missense Mutation (SNP) | VAF 14/142 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV58995175; called by muse, mutect2
- OR56A4 | c.971C>A p.P324H | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV58110508; called by muse, mutect2, varscan2
- OR5J2 | c.430C>T p.L144F | Missense Mutation (SNP) | VAF 21/240 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV56621791; called by muse, mutect2
- OR5J2 | c.719C>A p.T240N | Missense Mutation (SNP) | VAF 11/204 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56621263; called by muse, mutect2
- OR7E24 | c.245C>A p.S82Y | Missense Mutation (SNP) | VAF 88/489 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV71702215; called by muse, mutect2, varscan2
- OS9 | c.1060G>T p.V354L | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV99067171; called by muse, mutect2, varscan2
- OVCH1 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 38/220 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV58966594; called by muse, mutect2
- PCDHB13 | c.18G>T p.K6N | Missense Mutation (SNP) | VAF 89/448 reads (20%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.005); catalogued as COSV53396373; called by muse, mutect2, varscan2
- PCDHB3 | c.1954C>G p.R652G | Missense Mutation (SNP) | VAF 100/707 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV99164091; called by muse, mutect2, varscan2
- PCDHGA10 | c.457G>T p.G153* | Nonsense Mutation (SNP) | VAF 110/395 reads (28%) | catalogued as COSV53998798; called by muse, mutect2, varscan2
- PDZD2 | c.396G>C p.K132N | Missense Mutation (SNP) | VAF 38/518 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as rs760487874; called by muse, mutect2
- PHOX2B | c.187G>T p.G63* | Nonsense Mutation (SNP) | VAF 39/227 reads (17%) | catalogued as COSV56930767; called by muse, mutect2, varscan2
- PIP4P2 | c.182G>T p.C61F | Missense Mutation (SNP) | VAF 28/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV53439632; called by muse, mutect2, varscan2
- PKHD1L1 | c.5492C>T p.P1831L | Missense Mutation (SNP) | VAF 52/271 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as rs1330376459, COSV101005171, COSV65753827; called by muse, mutect2, varscan2
- PLB1 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 30/216 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as COSV100214923; called by muse, mutect2, varscan2
- PLEC | c.3708G>T p.Q1236H (on ENST00000322810 / NM_201380.4; = p.Q1126H on NM_000445.5) | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV59639561; called by muse, mutect2
- PLEKHA3 | c.202G>T p.E68* | Nonsense Mutation (SNP) | VAF 18/142 reads (13%) | catalogued as COSV99317667; called by muse, mutect2, varscan2
- PLK3 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 42/584 reads (7%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0.003); catalogued as rs968361297; called by muse, mutect2
- PNLDC1 | c.1076G>A p.G359E | Missense Mutation (SNP) | VAF 38/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs149462285; called by muse, mutect2, varscan2
- POM121L12 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 43/236 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.082); catalogued as rs541507226, COSV68692510; called by muse, mutect2, varscan2
- POPDC2 | c.770G>T p.G257V | Missense Mutation (SNP) | VAF 43/358 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99951237; called by muse, mutect2, varscan2
- POT1 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.074); catalogued as CM1412278, COSV100714126; called by muse, mutect2
- POTEE | c.2525T>A p.L842Q | Missense Mutation (SNP) | VAF 47/1001 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs200048663; called by muse, mutect2
- PPRC1 | c.302C>G p.S101C | Missense Mutation (SNP) | VAF 11/215 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99531329; called by muse, mutect2
- PRAG1 | c.189G>T p.R63S | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.844); catalogued as rs868616357, COSV58167492; called by muse, mutect2, varscan2
- PRDM9 | c.2610C>G p.S870R | Missense Mutation (SNP) | VAF 38/636 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.108); catalogued as COSV99690106; called by muse, mutect2
- PTPN1 | c.1027G>T p.D343Y | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV100860580; called by muse, mutect2, varscan2
- PXDNL | c.757T>A p.F253I | Missense Mutation (SNP) | VAF 19/176 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV62483430; called by muse, mutect2, varscan2
- RALGAPA2 | c.1802C>A p.T601K | Missense Mutation (SNP) | VAF 18/197 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52493635; called by muse, mutect2
- RAPGEF4 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 12/104 reads (12%) | catalogued as COSV99909552; called by muse, mutect2, varscan2
- RC3H1 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 47/423 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51202474; called by muse, mutect2, varscan2
- RGPD3 | c.58C>T p.P20S | Missense Mutation (SNP) | VAF 33/706 reads (5%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.857); catalogued as rs771715057; called by muse, mutect2
- RGS7BP | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs1270718895, COSV61836052; called by muse, mutect2
- RIMS2 | c.4736C>A p.S1579* (on ENST00000666250 / NM_001348490.2; = p.S1150* on NM_014677.5 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 49/281 reads (17%) | catalogued as rs755463325, COSV51657623; called by muse, mutect2, varscan2
- RLF | c.3059G>T p.S1020I | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.24); catalogued as COSV101035867; called by muse, mutect2, varscan2
- RYR1 | c.4718C>A p.P1573Q | Missense Mutation (SNP) | VAF 81/664 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM122393; called by muse, mutect2, varscan2
- RYR2 | c.4747C>A p.P1583T | Missense Mutation (SNP) | VAF 22/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1411475; called by muse, mutect2, varscan2
- RYR3 | c.6305G>T p.R2102L | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781486899, COSV66788246, COSV66796570; called by muse, mutect2, varscan2
- SCN2A | c.57G>T p.R19S | Missense Mutation (SNP) | VAF 38/548 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.184); catalogued as rs1409575197; called by muse, mutect2
- SCN5A | c.4822C>T p.L1608F (on ENST00000333535 / NM_198056.3; = p.L1607F on NM_000335.5) | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.769); catalogued as COSV61119736; called by muse, mutect2
- SDK2 | c.919C>A p.P307T | Missense Mutation (SNP) | VAF 46/352 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); catalogued as rs1175876466; called by muse, mutect2, varscan2
- SERBP1 | c.262G>T p.V88L | Missense Mutation (SNP) | VAF 23/188 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.005); catalogued as rs1249581140; called by muse, mutect2
- SGIP1 | c.1115C>A p.S372* | Nonsense Mutation (SNP) | VAF 26/278 reads (9%) | catalogued as COSV52778856; called by muse, mutect2
- SH2D5 | c.838G>A p.G280S (on ENST00000444387 / NM_001103161.2; = p.G196S on NM_001103160.2) | Missense Mutation (SNP) | VAF 39/272 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0.137); catalogued as rs754707626; called by muse, mutect2, varscan2
- SHISA6 | c.610C>A p.R204S | Missense Mutation (SNP) | VAF 144/800 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as rs1261033923, COSV100603828; called by muse, mutect2, varscan2
- SHOC1 | c.1499C>G p.S500C | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.621); catalogued as COSV59506248; called by muse, mutect2, varscan2
- SI | c.412C>A p.L138I | Missense Mutation (SNP) | VAF 24/232 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.051); catalogued as COSV100013832, COSV52302424; called by muse, mutect2, varscan2
- SIPA1L2 | c.2532G>T p.R844S | Missense Mutation (SNP) | VAF 34/336 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV53394711; called by muse, mutect2, varscan2
- SKOR2 | c.1355G>C p.G452A | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.902); catalogued as rs1269721816; called by muse, mutect2
- SLC22A6 | c.1438G>T p.E480* | Nonsense Mutation (SNP) | VAF 56/547 reads (10%) | catalogued as COSV64560269; called by muse, mutect2
- SLC25A2 | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.035); catalogued as COSV53403603; called by muse, mutect2, varscan2
- SLC4A10 | c.1103C>A p.T368N (on ENST00000446997 / NM_001354461.2; = p.T338N on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1039822470, COSV99763035; called by muse, mutect2
- SLC7A13 | c.227G>T p.C76F | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT tolerated (0.7); PolyPhen benign (0.005); catalogued as rs1198658178, COSV52538056; called by muse, mutect2, varscan2
- SLITRK1 | c.1799C>T p.A600V | Missense Mutation (SNP) | VAF 36/425 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs377623606; called by muse, mutect2
- SNX18 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as rs1442947971; called by muse, mutect2
- SNX19 | c.815G>C p.R272T | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV56284842; called by muse, mutect2
- SPANXC | c.40G>T p.V14F | Missense Mutation (SNP) | VAF 20/152 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); catalogued as COSV62842114, COSV62842334; called by muse, mutect2
- SPATA21 | c.94G>T p.G32W | Missense Mutation (SNP) | VAF 10/246 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); catalogued as CM1212862; called by muse, mutect2
- STK11 | c.298C>T p.Q100* | Nonsense Mutation (SNP) | VAF 28/115 reads (24%) | catalogued as CM991151, COSV58822329, COSV58830813; called by muse, mutect2, varscan2
- SYT3 | c.1246C>A p.R416S | Missense Mutation (SNP) | VAF 25/188 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as COSV100143738; called by muse, mutect2, varscan2
- TAC4 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 18/215 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen possibly damaging (0.814); catalogued as rs749887131; called by muse, mutect2
- TAS1R2 | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 65/466 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs372694127; called by muse, mutect2, varscan2
- TCEAL2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 39/147 reads (27%) | catalogued as COSV61197546; called by muse, mutect2, varscan2
- TCF21 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 47/333 reads (14%) | SIFT tolerated (0.68); PolyPhen benign (0.038); catalogued as COSV52819859; called by muse, varscan2
- TCHH | c.4225C>T p.R1409C | Missense Mutation (SNP) | VAF 57/417 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); catalogued as rs760292203; called by muse, mutect2, varscan2
- TENM3 | c.2654C>T p.S885L | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as rs992686597, COSV69315235; called by muse, mutect2
- TEX44 | c.850G>A p.E284K | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748841590, COSV58355136, COSV58355254; called by muse, mutect2
- THSD7B | c.3314T>A p.V1105E (on ENST00000272643; = p.V1103E on NM_001316349.2) | Missense Mutation (SNP) | VAF 25/193 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1407299739; called by muse, mutect2, varscan2
- TLR4 | c.2002G>T p.G668C (on ENST00000355622 / NM_138554.5; = p.G628C on NM_003266.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV100842681; called by muse, mutect2, varscan2
- TMEM117 | c.688G>T p.G230* | Nonsense Mutation (SNP) | VAF 19/271 reads (7%) | catalogued as COSV56897155; called by muse, mutect2
- TMEM139 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.714); catalogued as COSV100130869; called by muse, mutect2
- TMPRSS7 | c.2299G>T p.G767W (on ENST00000452346; = p.G641W on NM_001042575.2) | Missense Mutation (SNP) | VAF 21/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69980712; called by muse, mutect2
- TNK2 | c.1699G>C p.E567Q | Missense Mutation (SNP) | VAF 41/474 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.437); catalogued as rs770581073; called by muse, mutect2
- TNNT1 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 32/487 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766278869, COSV99402839; called by muse, mutect2
- TNR | c.2911C>A p.L971M | Missense Mutation (SNP) | VAF 12/196 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1396814891; called by muse, mutect2
- TP53 | c.470dup p.R158Pfs*23 | Frame Shift Ins (INS) | VAF 34/274 reads (12%) | catalogued as COSV53797156; called by mutect2, varscan2
- TP53 | c.469delinsTT p.V157Ffs*24 | Frame Shift Ins (INS) | VAF 22/275 reads (8%) | catalogued as CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; called by mutect2*, pindel, varscan2*
- TSHZ3 | c.2846G>T p.W949L | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53679682; called by muse, mutect2, varscan2
- TUBG1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 32/301 reads (11%) | catalogued as COSV52221710; called by muse, mutect2, varscan2
- UNC93B1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 24/219 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0.017); catalogued as rs374178199; called by muse, mutect2, varscan2
- USH2A | c.12327G>T p.E4109D | Missense Mutation (SNP) | VAF 59/435 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1485003545; called by muse, mutect2, varscan2
- VAC14 | c.1169G>C p.R390T | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1567581063; called by muse, mutect2
- VARS2 | c.2686C>T p.Q896* | Nonsense Mutation (SNP) | VAF 16/160 reads (10%) | catalogued as rs1205118546; called by muse, mutect2, varscan2
- VCAN | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 17/232 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV54116707; called by muse, mutect2
- VPS28 | c.300+1G>A p.X100_splice | Splice Site (SNP) | VAF 53/253 reads (21%) | catalogued as rs368919189, COSV52872624; called by muse, mutect2, varscan2
- WASH6P | c.1241C>T p.A414V | Missense Mutation (SNP) | VAF 132/970 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.221); catalogued as rs1473606060; called by muse, varscan2
- WASHC2C | c.1441G>T p.D481Y | Missense Mutation (SNP) | VAF 24/362 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as COSV100313738; called by muse, mutect2
- WASHC5 | c.1964G>A p.R655H | Missense Mutation (SNP) | VAF 79/509 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs766466433; called by muse, mutect2, varscan2
- WWOX | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.696); catalogued as rs746317044; called by muse, mutect2, varscan2
- WWTR1 | c.266C>G p.S89W | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100640934; called by muse, mutect2, varscan2
- ZFP62 | c.2354A>G p.Y785C (on ENST00000502412 / NM_001377944.1; = p.Y752C on NM_152283.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 44/162 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs755421914; called by muse, mutect2, varscan2
- ZIC4 | c.611T>A p.F204Y | Missense Mutation (SNP) | VAF 56/419 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1229691545; called by muse, mutect2, varscan2
- ZIM3 | c.942G>T p.K314N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54143317; called by mutect2, varscan2
- ZKSCAN5 | c.487C>T p.H163Y | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs201443792, COSV58741645, COSV58743997; called by muse, mutect2, varscan2
- ZNF230 | c.1192G>T p.G398W | Missense Mutation (SNP) | VAF 48/382 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1191165627; called by muse, mutect2, varscan2
- ZNF423 | c.2534C>A p.T845N (on ENST00000563137 / NM_001379286.1; = p.T837N on NM_015069.4) | Missense Mutation (SNP) | VAF 54/260 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs368649166; called by muse, mutect2, varscan2
- ZNF492 | c.1466C>G p.S489C | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs775715406; called by muse, mutect2
- ZNF536 | c.3123C>A p.C1041* | Nonsense Mutation (SNP) | VAF 34/328 reads (10%) | catalogued as COSV100835442; called by muse, mutect2, varscan2
- ZNF727 | c.43C>A p.P15T | Missense Mutation (SNP) | VAF 35/350 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.239); catalogued as COSV71647101; called by muse, mutect2, varscan2
- AACS | c.605A>T p.K202M | Missense Mutation (SNP) | VAF 12/293 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ABCA1 | c.622G>A p.D208N | Missense Mutation (SNP) | VAF 104/410 reads (25%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABCA12 | c.1517del p.P506Qfs*6 (on ENST00000272895 / NM_173076.3; = p.P188Qfs*6 on NM_015657.3) | Frame Shift Del (DEL) | VAF 18/245 reads (7%) | called by mutect2, pindel*
- ABCG5 | c.565A>T p.S189C | Missense Mutation (SNP) | VAF 40/923 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.205); called by muse, mutect2
- AC004922.1 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 62/445 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- AC099489.1 | c.4022G>T p.R1341L | Missense Mutation (SNP) | VAF 46/444 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- AC242842.3 | c.5159G>C p.R1720T | Missense Mutation (SNP) | VAF 8/544 reads (1%) | SIFT deleterious (0.05); PolyPhen benign (0.402); called by muse, mutect2
- ACAN | c.4705C>A p.L1569I | Missense Mutation (SNP) | VAF 65/523 reads (12%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACE | c.1039A>T p.M347L | Missense Mutation (SNP) | VAF 40/282 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- ACOX2 | c.839A>G p.Y280C | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); called by muse, mutect2, varscan2
- ACSBG1 | c.2026C>A p.P676T | Missense Mutation (SNP) | VAF 48/452 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ACTRT1 | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ADAM12 | c.2084G>T p.S695I | Missense Mutation (SNP) | VAF 27/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADAMTS12 | c.2287G>T p.G763W | Missense Mutation (SNP) | VAF 32/458 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS15 | c.581G>T p.R194L | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- ADAMTS16 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 34/590 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADAMTS18 | c.2915A>T p.H972L | Missense Mutation (SNP) | VAF 141/666 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.407); called by muse, mutect2, varscan2
- ADCY2 | c.1435C>A p.P479T | Missense Mutation (SNP) | VAF 22/192 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADCY8 | c.3363G>T p.M1121I | Missense Mutation (SNP) | VAF 68/451 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGB | c.1785G>C p.Q595H | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRF4 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 36/382 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.372); called by muse, mutect2
- ADGRG4 | c.824C>A p.P275H | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- ADHFE1 | c.778A>T p.S260C | Missense Mutation (SNP) | VAF 20/256 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.033); called by muse, mutect2
- AHNAK2 | c.10343C>A p.A3448D | Missense Mutation (SNP) | VAF 179/888 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- AJAP1 | c.1085G>T p.R362M | Missense Mutation (SNP) | VAF 40/466 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- AJAP1 | c.1086G>T p.R362S | Missense Mutation (SNP) | VAF 38/468 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AKT1 | c.965A>G p.E322G | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- ALPK3 | c.3092T>C p.L1031P | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AMN | c.1323C>A p.F441L | Missense Mutation (SNP) | VAF 115/749 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- AMOT | c.97A>T p.S33C | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- AMPD3 | c.1009T>C p.Y337H (on ENST00000396553 / NM_001025389.2; = p.Y346H on NM_000480.3) | Missense Mutation (SNP) | VAF 119/545 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); called by muse, mutect2, varscan2
- AMTN | c.397C>A p.P133T | Missense Mutation (SNP) | VAF 46/269 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- ANLN | c.1796A>G p.E599G | Missense Mutation (SNP) | VAF 29/238 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- APOBEC3G | c.418C>G p.Q140E | Missense Mutation (SNP) | VAF 47/311 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ARHGAP42 | c.2377C>T p.Q793* | Nonsense Mutation (SNP) | VAF 15/148 reads (10%) | called by muse, mutect2
- ARHGAP5 | c.1308G>C p.K436N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.343); called by muse, mutect2
- ARID1B | c.2041G>A p.A681T | Missense Mutation (SNP) | VAF 42/322 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARL11 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 6/56 reads (11%) | called by muse, mutect2, varscan2
- ARMC4 | c.2867G>C p.R956T | Missense Mutation (SNP) | VAF 38/556 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.386); called by muse, mutect2
- ARMC8 | c.1155G>C p.M385I (on ENST00000469044 / NM_001363941.2; = p.M371I on NM_015396.6) | Missense Mutation (SNP) | VAF 27/336 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2
- ARMH3 | c.1813G>C p.E605Q | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- ARRB1 | c.230A>G p.K77R | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.914); called by muse, mutect2
- ASH2L | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.847); called by mutect2, varscan2
- ASPN | c.65C>G p.S22* | Nonsense Mutation (SNP) | VAF 56/252 reads (22%) | called by muse, varscan2
- ASTN1 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 14/230 reads (6%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2
- ATF7IP2 | c.195del p.K66Nfs*31 | Frame Shift Del (DEL) | VAF 15/201 reads (7%) | called by mutect2, pindel*
- ATN1 | c.2429G>C p.R810P | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- ATP12A | c.1261del p.H421Ifs*19 | Frame Shift Del (DEL) | VAF 9/86 reads (10%) | called by mutect2, pindel, varscan2
- ATP13A2 | c.1558G>A p.E520K | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- B3GNT9 | c.764G>A p.G255D | Missense Mutation (SNP) | VAF 23/285 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BAK1 | c.530G>T p.W177L | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCCIP | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 26/179 reads (15%) | SIFT tolerated (0.72); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- BEGAIN | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 46/284 reads (16%) | called by muse, varscan2
- BEST3 | c.1214C>A p.P405H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2
- BHMT2 | c.1007C>A p.A336E | Missense Mutation (SNP) | VAF 26/195 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- BNC1 | c.1048C>G p.L350V | Missense Mutation (SNP) | VAF 30/262 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- BPIFB3 | c.794G>T p.R265L | Missense Mutation (SNP) | VAF 30/165 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- BTN2A2 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 58/490 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- C16orf96 | c.2078T>C p.I693T | Missense Mutation (SNP) | VAF 47/280 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- CACNA1E | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- CACNA1S | c.251T>A p.L84H | Missense Mutation (SNP) | VAF 37/717 reads (5%) | SIFT tolerated (0.78); PolyPhen benign (0.05); called by muse, mutect2
- CALCRL | c.498C>A p.F166L | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.734); called by muse, mutect2
- CAP2 | c.431G>C p.G144A | Missense Mutation (SNP) | VAF 25/153 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CAPN14 | c.602T>A p.L201H | Missense Mutation (SNP) | VAF 16/214 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- CASK | c.36C>A p.Y12* | Nonsense Mutation (SNP) | VAF 53/213 reads (25%) | called by muse, mutect2, varscan2
- CASP9 | c.530T>A p.L177H | Missense Mutation (SNP) | VAF 41/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CBLB | c.642G>T p.M214I | Missense Mutation (SNP) | VAF 27/317 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.243); called by muse, mutect2
- CCBE1 | c.400G>T p.D134Y | Missense Mutation (SNP) | VAF 23/507 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CCDC168 | c.8560G>A p.D2854N | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- CCDC3 | c.272T>C p.L91P | Missense Mutation (SNP) | VAF 80/499 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CCDC39 | c.1056T>G p.H352Q | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2
- CD1E | c.670G>T p.G224C | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CDC45 | c.1445A>G p.K482R | Missense Mutation (SNP) | VAF 35/281 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CDC45 | c.1446G>T p.K482N | Missense Mutation (SNP) | VAF 34/292 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- CDH13 | c.2104G>T p.V702F | Missense Mutation (SNP) | VAF 97/440 reads (22%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- CDH20 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CDK5R2 | c.619G>T p.G207C | Missense Mutation (SNP) | VAF 91/700 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CDK5RAP2 | c.892G>T p.D298Y | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CELF6 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 31/260 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- CEP350 | c.775C>G p.P259A | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2
- CFAP46 | c.6676G>T p.A2226S | Missense Mutation (SNP) | VAF 39/324 reads (12%) | SIFT tolerated (0.12); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- CFAP74 | c.1774C>G p.L592V | Missense Mutation (SNP) | VAF 8/159 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2
- CHAT | c.902C>A p.P301H | Missense Mutation (SNP) | VAF 18/351 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2
- CHD8 | c.6630C>G p.D2210E (on ENST00000646647 / NM_001170629.2; = p.D1931E on NM_020920.4) | Missense Mutation (SNP) | VAF 67/495 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CIP2A | c.2634G>C p.L878F | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CLDN19 | c.284T>A p.M95K | Missense Mutation (SNP) | VAF 33/503 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.433); called by muse, mutect2
- CLPB | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.261); called by muse, mutect2
- CLPS | c.163C>A p.R55S | Missense Mutation (SNP) | VAF 26/418 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CNGB1 | c.2776C>A p.H926N | Missense Mutation (SNP) | VAF 120/570 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CNTNAP5 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 32/260 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- CNTNAP5 | c.2687G>C p.S896T | Missense Mutation (SNP) | VAF 32/455 reads (7%) | SIFT tolerated (0.26); PolyPhen benign (0.031); called by muse, mutect2
- COL15A1 | c.1484del p.P495Lfs*63 | Frame Shift Del (DEL) | VAF 53/216 reads (25%) | called by pindel, varscan2
- COL19A1 | c.289C>A p.P97T | Missense Mutation (SNP) | VAF 9/89 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.419); called by mutect2, varscan2
- COL26A1 | c.1210C>A p.L404M (on ENST00000313669 / NM_001278563.3; = p.L402M on NM_133457.4) | Missense Mutation (SNP) | VAF 40/266 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- COL5A3 | c.1339-3C>A | Splice Region (SNP) | VAF 38/223 reads (17%) | called by muse, mutect2, varscan2
- COL9A1 | c.2410C>A p.P804T | Missense Mutation (SNP) | VAF 34/298 reads (11%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.882); called by muse, mutect2, varscan2
- COQ3 | c.779A>G p.Y260C | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- CREM | c.59A>T p.E20V | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); called by muse, mutect2
- CSMD1 | c.4367T>A p.L1456Q (on ENST00000520002; = p.L1455Q on NM_033225.6) | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- CSMD3 | c.9925T>A p.Y3309N (on ENST00000297405 / NM_001363185.1; = p.Y3140N on NM_052900.3) | Missense Mutation (SNP) | VAF 12/228 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CSMD3 | c.78A>T p.K26N | Missense Mutation (SNP) | VAF 81/444 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- CSPG4 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 42/306 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- CTAGE6 | c.1558C>T p.P520S | Missense Mutation (SNP) | VAF 30/637 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2
- CTLA4 | c.34C>T p.Q12* | Nonsense Mutation (SNP) | VAF 25/255 reads (10%) | called by muse, mutect2
- CUX2 | c.2852C>A p.P951H | Missense Mutation (SNP) | VAF 39/575 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYP11B2 | c.836C>T p.A279V | Missense Mutation (SNP) | VAF 29/502 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.081); called by muse, mutect2
- CYP3A7 | c.1201C>G p.L401V | Missense Mutation (SNP) | VAF 41/402 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DAGLA | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 14/198 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); called by muse, mutect2
- DCAF8L2 | c.467G>T p.S156I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- DCLK2 | c.1372G>T p.E458* | Nonsense Mutation (SNP) | VAF 10/164 reads (6%) | called by muse, mutect2
- DDX3X | c.451dup p.S151Ffs*8 (on ENST00000399959; = p.S152Ffs*8 on NM_001356.5) | Frame Shift Ins (INS) | VAF 10/55 reads (18%) | called by mutect2, pindel, varscan2
- DDX42 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- DENND4B | c.4278G>A p.Q1426= | Splice Region (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- DEPDC1 | c.1935+1G>T p.X645_splice (on ENST00000456315 / NM_001114120.3; = p.X361_splice on NM_017779.6) | Splice Site (SNP) | VAF 5/43 reads (12%) | called by mutect2, varscan2
- DES | c.955C>T p.Q319* | Nonsense Mutation (SNP) | VAF 47/795 reads (6%) | called by muse, mutect2
- DIO2 | c.318dup p.A107Sfs*2 | Frame Shift Ins (INS) | VAF 46/278 reads (17%) | called by mutect2, pindel, varscan2
- DIS3L2 | c.367-1G>T p.X123_splice | Splice Site (SNP) | VAF 8/66 reads (12%) | called by muse, mutect2, varscan2
- DMBT1 | c.2330G>C p.G777A | Missense Mutation (SNP) | VAF 54/752 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- DMBT1 | c.5117G>T p.R1706L (on ENST00000338354 / NM_001377530.1; = p.R949L on NM_004406.3) | Missense Mutation (SNP) | VAF 53/886 reads (6%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.955); called by muse, mutect2
- DMWD | c.1809G>T p.Q603H | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- DMXL1 | c.5952A>T p.K1984N | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- DNAAF5 | c.515G>C p.R172P | Missense Mutation (SNP) | VAF 30/245 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- DNAH11 | c.4960G>C p.A1654P | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- DNAH11 | c.10219C>A p.L3407I | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DNAH2 | c.1396G>C p.D466H | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- DNAI2 | c.1252G>T p.V418L | Missense Mutation (SNP) | VAF 80/665 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- DNAJB4 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 10/171 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- DNMT1 | c.233A>T p.Y78F | Missense Mutation (SNP) | VAF 91/431 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- DOK3 | c.1146G>C p.L382F | Missense Mutation (SNP) | VAF 56/494 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- DPP6 | c.2248T>A p.S750T (on ENST00000377770 / NM_001364500.2; = p.S688T on NM_001936.5) | Missense Mutation (SNP) | VAF 83/551 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- DPYD | c.484G>T p.V162L | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- DTWD1 | c.377G>T p.C126F | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2
- EFCAB3 | c.1250C>A p.T417N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2, varscan2
- EIF2S2 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by mutect2, varscan2
- EIF4G3 | c.4513G>C p.E1505Q | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ELFN1 | c.1207C>A p.P403T | Missense Mutation (SNP) | VAF 43/330 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EML5 | c.3608G>A p.S1203N | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2
- EN1 | c.1158G>C p.Q386H | Missense Mutation (SNP) | VAF 19/216 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.949); called by muse, mutect2
- EPB41L3 | c.1425G>T p.E475D | Missense Mutation (SNP) | VAF 46/364 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- EPS8L3 | c.1041C>G p.I347M | Missense Mutation (SNP) | VAF 31/245 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- ERAS | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 16/140 reads (11%) | called by muse, mutect2, varscan2
- ERC2 | c.1840G>C p.E614Q | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2
- ERICH3 | c.4445G>T p.G1482V | Missense Mutation (SNP) | VAF 30/323 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.022); called by muse, mutect2
- ERMARD | c.1959G>C p.L653F | Missense Mutation (SNP) | VAF 6/97 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.445); called by muse, mutect2
- ESPNL | c.2884G>C p.E962Q | Missense Mutation (SNP) | VAF 30/472 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.01); called by muse, mutect2
- ESRRB | c.787+1G>T p.X263_splice | Splice Site (SNP) | VAF 77/482 reads (16%) | called by muse, mutect2, varscan2
- F5 | c.4590G>T p.E1530D | Missense Mutation (SNP) | VAF 29/382 reads (8%) | SIFT tolerated (0.29); PolyPhen benign (0.006); called by muse, mutect2
- FAM111A | c.1282G>T p.E428* | Nonsense Mutation (SNP) | VAF 16/153 reads (10%) | called by muse, mutect2, varscan2
- FAM205A | c.2163C>G p.F721L | Missense Mutation (SNP) | VAF 99/821 reads (12%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2, varscan2
- FANCM | c.1162G>T p.G388* | Nonsense Mutation (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- FAT3 | c.9779C>A p.A3260D | Missense Mutation (SNP) | VAF 26/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- FAT4 | c.1612G>T p.G538W | Missense Mutation (SNP) | VAF 25/216 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBH1 | c.2563G>C p.E855Q (on ENST00000362091 / NM_178150.3; = p.E906Q on NM_032807.4) | Missense Mutation (SNP) | VAF 10/289 reads (3%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.464); called by muse, mutect2
- FBLN5 | c.1274T>G p.V425G | Missense Mutation (SNP) | VAF 110/590 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FBXL19 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 14/106 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2, varscan2
- FLNB | c.7306G>A p.E2436K | Missense Mutation (SNP) | VAF 72/506 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FLNC | c.3955T>A p.Y1319N | Missense Mutation (SNP) | VAF 51/354 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); called by muse, mutect2, varscan2
- FMN2 | c.379G>T p.E127* | Nonsense Mutation (SNP) | VAF 21/352 reads (6%) | called by muse, mutect2
- FRMPD4 | c.788T>C p.L263P | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- FSCN3 | c.138G>C p.R46S | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FSIP2 | c.14597C>G p.S4866C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); called by muse, mutect2, varscan2
- FTSJ3 | c.610G>A p.D204N | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.047); called by muse, mutect2
- FXR1 | c.46T>A p.Y16N | Missense Mutation (SNP) | VAF 26/436 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); called by muse, mutect2
- GALNT17 | c.1635G>C p.K545N | Missense Mutation (SNP) | VAF 37/272 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- GAP43 | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 28/223 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GDF5 | c.1246G>T p.D416Y | Missense Mutation (SNP) | VAF 72/581 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GNAL | c.144G>A p.L48= | Splice Region (SNP) | VAF 21/399 reads (5%) | called by muse, mutect2
- GNL1 | c.74-1G>C p.X25_splice | Splice Site (SNP) | VAF 16/162 reads (10%) | called by muse, mutect2
- GOLIM4 | c.1234G>T p.E412* | Nonsense Mutation (SNP) | VAF 60/459 reads (13%) | called by muse, varscan2
- GPATCH8 | c.517G>T p.E173* | Nonsense Mutation (SNP) | VAF 36/292 reads (12%) | called by muse, mutect2, varscan2
- GPR155 | c.1674G>C p.Q558H | Missense Mutation (SNP) | VAF 26/338 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2
- GRIA4 | c.1894C>A p.L632I | Missense Mutation (SNP) | VAF 21/236 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); called by muse, mutect2
- GRID2 | c.1293C>A p.D431E | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- GSTA5 | c.494A>T p.Y165F | Missense Mutation (SNP) | VAF 55/443 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GTF2A1 | c.776A>T p.Q259L | Missense Mutation (SNP) | VAF 28/508 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.932); called by muse, mutect2
- GTPBP3 | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 33/197 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- H2BC6 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 38/366 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.03); called by muse, mutect2
- HEATR4 | c.1121T>A p.L374Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HECTD1 | c.3760G>A p.E1254K | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- HECW2 | c.4030A>T p.S1344C | Missense Mutation (SNP) | VAF 20/109 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- HERPUD1 | c.226-8A>T | Splice Region (SNP) | VAF 64/233 reads (27%) | called by muse, mutect2, varscan2
- HMCN1 | c.204G>T p.E68D | Missense Mutation (SNP) | VAF 40/255 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN2 | c.2226G>C p.E742D | Missense Mutation (SNP) | VAF 18/244 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.031); called by muse, mutect2
- HNF4A | c.338G>T p.R113L | Missense Mutation (SNP) | VAF 83/687 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HRNR | c.6121A>T p.S2041C | Missense Mutation (SNP) | VAF 59/1742 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.887); called by muse, mutect2
- HRNR | c.2978C>A p.S993Y | Missense Mutation (SNP) | VAF 95/982 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- HSPA13 | c.1174G>T p.G392C | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HTR3D | c.437C>G p.S146* (on ENST00000382489 / NM_001163646.2; = p.S11* on NM_182537.3) | Nonsense Mutation (SNP) | VAF 30/236 reads (13%) | called by muse, varscan2
- ICE1 | c.3614A>T p.E1205V | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- IDH3A | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 41/361 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- IDUA | c.1755C>G p.F585L | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- IFNLR1 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.878); called by muse, mutect2
- IGFBP1 | c.125C>G p.P42R | Missense Mutation (SNP) | VAF 80/760 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV2D-30 | c.354C>A p.H118Q | Missense Mutation (SNP) | VAF 46/520 reads (9%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2
- IGKV3-15 | c.343C>A p.P115T | Missense Mutation (SNP) | VAF 30/856 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGLV3-10 | c.46G>T p.V16F | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2
- IL2RG | c.756A>T p.K252N | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- IMPG1 | c.688G>T p.V230L | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- INHBE | c.959G>T p.R320L | Missense Mutation (SNP) | VAF 20/417 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.098); called by muse, mutect2
- IRF2BPL | c.1559C>T p.A520V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2
- JADE1 | c.880C>G p.P294A | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JPH4 | c.122G>C p.G41A | Missense Mutation (SNP) | VAF 40/355 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KANK4 | c.899T>A p.L300Q | Missense Mutation (SNP) | VAF 20/232 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.799); called by muse, mutect2
- KCNA1 | c.1359G>T p.E453D | Missense Mutation (SNP) | VAF 20/314 reads (6%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.001); called by muse, mutect2
- KCNB2 | c.2332C>G p.Q778E | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.151); called by muse, mutect2
- KCNH7 | c.2055G>T p.E685D | Missense Mutation (SNP) | VAF 18/288 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.298); called by muse, mutect2
- KCNH8 | c.2731C>A p.H911N | Missense Mutation (SNP) | VAF 65/569 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- KCNK10 | c.1399G>T p.E467* | Nonsense Mutation (SNP) | VAF 97/637 reads (15%) | called by muse, mutect2, varscan2
- KCNK9 | c.570C>A p.Y190* | Nonsense Mutation (SNP) | VAF 96/514 reads (19%) | called by muse, mutect2, varscan2
- KIAA1586 | c.2037A>G p.I679M | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.206); called by muse, mutect2
- KIF21B | c.2572G>A p.E858K | Missense Mutation (SNP) | VAF 46/708 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.115); called by muse, mutect2
- KIR2DL3 | c.11T>A p.M4K | Missense Mutation (SNP) | VAF 33/1115 reads (3%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.017); called by muse, mutect2
- KLHL21 | c.1037C>T p.S346F | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); called by muse, mutect2
- KRIT1 | c.1316G>A p.G439E | Missense Mutation (SNP) | VAF 12/99 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KRTAP10-2 | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 112/1010 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.137); called by muse, varscan2
- KRTAP4-7 | c.76C>A p.R26S | Missense Mutation (SNP) | VAF 51/384 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- LACTBL1 | c.298G>T p.A100S (on ENST00000618559; = p.A129S on NM_001289974.2) | Missense Mutation (SNP) | VAF 20/422 reads (5%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- LCT | c.3297A>T p.K1099N | Missense Mutation (SNP) | VAF 21/137 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LILRA5 | c.763+1G>T p.X255_splice | Splice Site (SNP) | VAF 32/304 reads (11%) | called by muse, mutect2
- LILRA5 | c.763G>T p.A255S | Missense Mutation (SNP) | VAF 32/305 reads (10%) | SIFT tolerated (0.3); PolyPhen benign (0.01); called by muse, mutect2
- LILRB1 | c.206C>A p.A69D (on ENST00000427581; = p.A33D on NM_006669.6) | Missense Mutation (SNP) | VAF 20/218 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LIPF | c.960+1G>T p.X320_splice | Splice Site (SNP) | VAF 7/69 reads (10%) | called by muse, mutect2
- LRP12 | c.730G>T p.D244Y | Missense Mutation (SNP) | VAF 34/214 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.8035A>G p.K2679E | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- LRRC8B | c.430A>T p.S144C | Missense Mutation (SNP) | VAF 40/473 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- LRRTM1 | c.793G>T p.G265C | Missense Mutation (SNP) | VAF 40/361 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- LTBP1 | c.2274G>T p.K758N (on ENST00000404816 / NM_206943.4; = p.K432N on NM_000627.4) | Missense Mutation (SNP) | VAF 29/349 reads (8%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.743); called by muse, mutect2
- LYPD2 | c.319C>A p.L107M | Missense Mutation (SNP) | VAF 71/470 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- LYST | c.7200C>G p.F2400L | Missense Mutation (SNP) | VAF 17/127 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LYST | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 7/127 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); called by muse, mutect2
- MAGI2 | c.3604A>C p.T1202P | Missense Mutation (SNP) | VAF 26/346 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- MARCO | c.890A>T p.K297I | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- MCF2 | c.967A>T p.R323W | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.014); called by muse, mutect2
- MCF2L2 | c.1863G>C p.R621S | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- MED14 | c.760G>T p.V254F | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2
- MEGF8 | c.4312G>T p.G1438C (on ENST00000251268 / NM_001271938.2; = p.G1371C on NM_001410.3) | Missense Mutation (SNP) | VAF 58/442 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MERTK | c.1816C>G p.L606V | Missense Mutation (SNP) | VAF 24/404 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- MFGE8 | c.540+1G>A p.X180_splice | Splice Site (SNP) | VAF 43/468 reads (9%) | called by muse, mutect2
- MFN1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- MGA | c.1096del p.R366Vfs*2 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | called by mutect2, pindel*, varscan2
- MGAM2 | c.4936A>T p.T1646S | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- MGAT5B | c.1959G>T p.E653D (on ENST00000569840 / NM_001199172.2; = p.E651D on NM_144677.3) | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.013); called by muse, mutect2
- MIB2 | c.2597C>T p.A866V | Missense Mutation (SNP) | VAF 30/474 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2
- MME | c.1690T>C p.F564L | Missense Mutation (SNP) | VAF 67/559 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- MMEL1 | c.686G>T p.R229M | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2
- MON2 | c.1954C>T p.H652Y | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.61); called by muse, mutect2
- MPO | c.830C>A p.T277N | Missense Mutation (SNP) | VAF 42/560 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.124); called by muse, mutect2
- MS4A18 | c.140C>A p.P47Q | Missense Mutation (SNP) | VAF 29/433 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.463); called by muse, mutect2
- MS4A18 | c.323A>G p.Q108R | Missense Mutation (SNP) | VAF 31/249 reads (12%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- MT1B | c.108_122del p.C37_C41del | In Frame Del (DEL) | VAF 78/396 reads (20%) | called by mutect2, pindel, varscan2
- MTR | c.3548A>G p.H1183R | Missense Mutation (SNP) | VAF 47/274 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MTUS2 | c.1543A>T p.N515Y | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.655); called by muse, mutect2
- MUC17 | c.833C>A p.T278K | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2
- MUC17 | c.1505C>A p.P502Q | Missense Mutation (SNP) | VAF 50/459 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- MUC3A | c.533C>A p.T178N | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious, low confidence (0.01); called by muse, mutect2, varscan2
- MYH7 | c.5157+1G>A p.X1719_splice | Splice Site (SNP) | VAF 70/932 reads (8%) | called by muse, mutect2
- MYO15A | c.2200del p.D734Tfs*3 | Frame Shift Del (DEL) | VAF 16/160 reads (10%) | called by mutect2, pindel
- MYO16 | c.160C>A p.P54T | Missense Mutation (SNP) | VAF 29/273 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- NAV1 | c.5257G>A p.E1753K | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- NBEAL2 | c.6541G>T p.V2181F | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.244); called by muse, mutect2, varscan2
- NBPF11 | c.705A>T p.K235N | Missense Mutation (SNP) | VAF 28/621 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.154); called by muse, mutect2
- NCOR1 | c.4481G>C p.R1494T | Missense Mutation (SNP) | VAF 21/126 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- NDUFAF4 | c.136+1G>T p.X46_splice | Splice Site (SNP) | VAF 42/391 reads (11%) | called by muse, mutect2, varscan2
- NELL2 | c.641C>G p.P214R | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFRKB | c.3566C>T p.S1189F (on ENST00000446488 / NM_001143835.2; = p.S1214F on NM_006165.3) | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NID1 | c.3034C>G p.P1012A | Missense Mutation (SNP) | VAF 25/395 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.674); called by muse, mutect2
- NISCH | c.2917G>C p.E973Q | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.906); called by muse, mutect2
- NLRP14 | c.1982G>T p.C661F | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP3 | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 42/735 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- NLRP7 | c.2941T>C p.*981Rext*38 (on ENST00000340844 / NM_206828.3; = p.*1010Rext*38 on NM_139176.3) | Nonstop Mutation (SNP) | VAF 76/623 reads (12%) | called by muse, mutect2, varscan2
- NOBOX | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 19/130 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.381); called by muse, mutect2, varscan2
- NPC1L1 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 97/442 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR0B2 | c.698G>T p.G233V | Missense Mutation (SNP) | VAF 62/459 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- NR5A2 | c.157G>T p.A53S | Missense Mutation (SNP) | VAF 30/515 reads (6%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); called by muse, mutect2
- NRXN3 | c.3244G>C p.G1082R (on ENST00000335750 / NM_001330195.2; = p.G709R on NM_004796.6) | Missense Mutation (SNP) | VAF 16/286 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.195); called by muse, mutect2
- NRXN3 | c.1169G>T p.G390V | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.96); called by muse, mutect2
- NUMA1 | c.254A>T p.Q85L | Missense Mutation (SNP) | VAF 27/295 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2
- NUP160 | c.3491G>T p.G1164V | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- NXPE4 | c.869C>A p.T290K (on ENST00000375478 / NM_001077639.2; = p.T6K on NM_017678.3) | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.31); PolyPhen benign (0.007); called by muse, mutect2
- OAS3 | c.594G>T p.K198N | Missense Mutation (SNP) | VAF 28/588 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OPN4 | c.196C>A p.P66T | Missense Mutation (SNP) | VAF 46/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OR2T4 | c.406T>A p.Y136N | Missense Mutation (SNP) | VAF 66/704 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- OR4A5 | c.694A>G p.K232E | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- OR6C74 | c.683C>T p.S228F | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- OSBPL1A | c.1012C>T p.H338Y | Missense Mutation (SNP) | VAF 16/304 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); called by muse, mutect2
- OTOGL | c.2388C>A p.P796= (on ENST00000547103; = p.P787= on NM_173591.4 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 9/132 reads (7%) | called by muse, mutect2
- PABPC5 | c.151dup p.R51Pfs*2 | Frame Shift Ins (INS) | VAF 35/181 reads (19%) | called by mutect2, pindel, varscan2
- PAFAH1B2 | c.263G>C p.G88A | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- PAK3 | c.715T>A p.S239T (on ENST00000262836 / NM_001324328.2; = p.S224T on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- PARP14 | c.2920G>T p.V974L | Missense Mutation (SNP) | VAF 30/251 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PAXBP1 | c.2735C>G p.S912C | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.436); called by muse, mutect2
- PBX1 | c.1070C>G p.S357C | Missense Mutation (SNP) | VAF 20/210 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); called by muse, mutect2
- PCDHB7 | c.2152G>T p.A718S | Missense Mutation (SNP) | VAF 267/1152 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.41); called by mutect2, varscan2
- PCDHGA4 | c.1082G>C p.R361T | Missense Mutation (SNP) | VAF 39/276 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCDHGB2 | c.1519G>T p.V507L | Missense Mutation (SNP) | VAF 154/640 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- PCDHGC4 | c.869G>C p.R290T | Missense Mutation (SNP) | VAF 36/282 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- PDZD7 | c.118A>G p.T40A | Missense Mutation (SNP) | VAF 39/697 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2
- PEX5L | c.238C>G p.P80A | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PGAP4 | c.428T>G p.L143R | Missense Mutation (SNP) | VAF 107/427 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- PHACTR2 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 18/201 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2
- PKD1 | c.9392G>A p.G3131D | Missense Mutation (SNP) | VAF 36/612 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCD4 | c.116G>C p.R39T | Missense Mutation (SNP) | VAF 30/215 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, varscan2
- PLCE1 | c.483G>T p.M161I | Missense Mutation (SNP) | VAF 18/162 reads (11%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLD5 | c.1580A>T p.D527V (on ENST00000442594; = p.D465V on NM_001195811.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/330 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.003); called by mutect2, varscan2
- PLEKHG5 | c.1549A>T p.M517L (on ENST00000400915 / NM_001042663.3; = p.M480L on NM_020631.6) | Missense Mutation (SNP) | VAF 19/342 reads (6%) | SIFT tolerated (0.39); PolyPhen benign (0.362); called by muse, mutect2
- PLOD2 | c.536T>A p.I179K | Missense Mutation (SNP) | VAF 14/145 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.421); called by muse, mutect2
- PLXNA4 | c.2837C>G p.S946* | Nonsense Mutation (SNP) | VAF 43/235 reads (18%) | called by muse, mutect2, varscan2
- PMFBP1 | c.1687G>A p.E563K (on ENST00000537465; = p.E558K on NM_031293.3) | Missense Mutation (SNP) | VAF 28/267 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- POPDC2 | c.769G>T p.G257W | Missense Mutation (SNP) | VAF 42/353 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POTEE | c.1125A>T p.P375= | Splice Region (SNP) | VAF 16/209 reads (8%) | called by muse, mutect2, varscan2
- POTEF | c.2116G>C p.A706P | Missense Mutation (SNP) | VAF 82/971 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); called by muse, mutect2
- PPAN-P2RY11 | c.126C>A p.N42K | Missense Mutation (SNP) | VAF 95/499 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- PPIL4 | c.1348G>C p.D450H | Missense Mutation (SNP) | VAF 53/357 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PPP1R21 | c.2270C>G p.S757C (on ENST00000294952 / NM_001135629.3; = p.S746C on NM_152994.5) | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- PPP2R2C | c.409G>T p.G137W | Missense Mutation (SNP) | VAF 18/210 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); called by muse, mutect2
- PPP6R3 | c.2131G>T p.E711* (on ENST00000393800 / NM_001352375.2; = p.E631* on NM_018312.5) | Nonsense Mutation (SNP) | VAF 15/249 reads (6%) | called by muse, mutect2
- PRAMEF14 | c.1196G>T p.C399F | Missense Mutation (SNP) | VAF 140/1083 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PRELID2 | c.422G>C p.R141T (on ENST00000334744 / NM_182960.4; = p.R100T on NM_138492.6) | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PRG4 | c.2477C>A p.T826N | Missense Mutation (SNP) | VAF 30/362 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2
- PROM1 | c.2338G>C p.D780H | Missense Mutation (SNP) | VAF 8/75 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PRPF39 | c.769A>G p.R257G | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.249); called by muse, mutect2
- PRRC2B | c.3284G>C p.G1095A | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PTCH2 | c.1521C>G p.I507M | Missense Mutation (SNP) | VAF 38/682 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.529); called by muse, mutect2
- PTCHD3 | c.868C>A p.H290N | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.185); called by muse, mutect2
- PTPRD | c.5662C>T p.Q1888* | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | called by muse, mutect2
- PTPRQ | c.3356C>A p.P1119Q (on ENST00000616559; = p.P1077Q on NM_001145026.2) | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PZP | c.2231C>G p.T744S | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PZP | c.157C>A p.L53M | Missense Mutation (SNP) | VAF 26/358 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBBP5 | c.52G>C p.D18H | Missense Mutation (SNP) | VAF 28/416 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RBP3 | c.682G>T p.V228L | Missense Mutation (SNP) | VAF 52/758 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.429); called by muse, mutect2
- RCSD1 | c.110C>A p.T37K | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.795); called by muse, mutect2, varscan2
- RDX | c.242G>C p.R81T | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- REG3A | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.703); called by muse, mutect2
- REPIN1 | c.1307G>A p.C436Y | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RIMKLB | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 10/117 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.009); called by muse, mutect2
- RP1L1 | c.1225A>G p.T409A | Missense Mutation (SNP) | VAF 46/486 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.224); called by muse, mutect2
- RPS8 | c.180G>T p.L60F | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- RTN4RL1 | c.434T>C p.F145S | Missense Mutation (SNP) | VAF 31/226 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RXFP3 | c.765G>C p.L255F | Missense Mutation (SNP) | VAF 68/354 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- RYR1 | c.8014C>A p.L2672M | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- RYR3 | c.1170C>A p.H390Q | Missense Mutation (SNP) | VAF 33/229 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SAMD9L | c.4457G>T p.S1486I | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.295); called by muse, mutect2
- SBF1 | c.1351del p.A451Qfs*81 | Frame Shift Del (DEL) | VAF 27/269 reads (10%) | called by mutect2, pindel, varscan2
- SCART1 | c.862G>T p.G288W | Missense Mutation (SNP) | VAF 28/190 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCRIB | c.1417C>G p.R473G | Missense Mutation (SNP) | VAF 32/178 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC16B | c.2971G>T p.A991S | Missense Mutation (SNP) | VAF 18/98 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SEC24C | c.2329G>C p.D777H | Missense Mutation (SNP) | VAF 46/406 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SEPTIN6 | c.84G>T p.L28F | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by mutect2, varscan2
- SGIP1 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 17/207 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); called by muse, mutect2
- SGK3 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- SH2D5 | c.839G>A p.G280D (on ENST00000444387 / NM_001103161.2; = p.G196D on NM_001103160.2) | Missense Mutation (SNP) | VAF 37/270 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- SH2D5 | c.512C>T p.P171L (on ENST00000444387 / NM_001103161.2; = p.P87L on NM_001103160.2) | Missense Mutation (SNP) | VAF 36/317 reads (11%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SHISA6 | c.1021C>A p.L341I (on ENST00000409168 / NM_001173461.1; = p.L392I on NM_207386.4) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- SIK2 | c.1744G>C p.E582Q | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIN3A | c.2338G>T p.A780S | Missense Mutation (SNP) | VAF 11/120 reads (9%) | SIFT tolerated (0.79); PolyPhen benign (0.003); called by muse, mutect2
- SIPA1L2 | c.2531G>T p.R844M | Missense Mutation (SNP) | VAF 35/338 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- SIPA1L2 | c.223G>T p.G75C | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SIPA1L3 | c.53G>A p.C18Y | Missense Mutation (SNP) | VAF 17/151 reads (11%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2
- SIX4 | c.583G>T p.E195* | Nonsense Mutation (SNP) | VAF 52/262 reads (20%) | called by muse, mutect2, varscan2
- SKOR2 | c.2600C>A p.P867H | Missense Mutation (SNP) | VAF 32/337 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- SLC17A1 | c.953C>T p.A318V | Missense Mutation (SNP) | VAF 18/214 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, mutect2
- SLC1A3 | c.688G>T p.E230* | Nonsense Mutation (SNP) | VAF 54/515 reads (10%) | called by muse, mutect2, varscan2
- SLC22A12 | c.884del p.G295Afs*21 | Frame Shift Del (DEL) | VAF 55/420 reads (13%) | called by mutect2, pindel, varscan2
- SLC35G4 | c.220A>C p.I74L | Missense Mutation (SNP) | VAF 52/697 reads (7%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- SLC4A1 | c.2403C>A p.S801R | Missense Mutation (SNP) | VAF 54/600 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2
- SLC4A3 | c.1886A>T p.Q629L | Missense Mutation (SNP) | VAF 93/603 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC4A7 | c.3465+1G>T p.X1155_splice | Splice Site (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- SLC6A15 | c.391G>T p.G131C | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC6A3 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 20/298 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- SLC6A7 | c.462G>T p.W154C | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC9A4 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 41/373 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLCO2B1 | c.1486C>A p.P496T | Missense Mutation (SNP) | VAF 39/332 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- SLITRK3 | c.1040C>A p.T347N | Missense Mutation (SNP) | VAF 45/308 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SMPDL3B | c.1310T>A p.V437E | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- SORCS1 | c.194C>G p.A65G | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- SOX5 | c.290T>A p.V97D | Missense Mutation (SNP) | VAF 54/320 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- SPATA31D1 | c.445C>A p.L149M | Missense Mutation (SNP) | VAF 105/572 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- SPTY2D1 | c.430G>T p.E144* | Nonsense Mutation (SNP) | VAF 26/97 reads (27%) | called by muse, mutect2, varscan2
- SQLE | c.461G>A p.R154K | Missense Mutation (SNP) | VAF 13/295 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SRGAP1 | c.808G>T p.D270Y | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ST18 | c.1095G>T p.E365D | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.268); called by muse, mutect2, varscan2
- STX12 | c.689T>C p.V230A | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- SUCO | c.2149G>A p.D717N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- SUPT4H1 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SVOP | c.1052C>A p.S351Y | Missense Mutation (SNP) | VAF 34/266 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- SYT16 | c.451A>G p.R151G | Missense Mutation (SNP) | VAF 29/170 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SYT3 | c.766C>A p.P256T | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT tolerated (0.63); PolyPhen benign (0.077); called by muse, mutect2
- SYT4 | c.629T>G p.V210G | Missense Mutation (SNP) | VAF 12/189 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SYTL2 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 32/195 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- TAF15 | c.185-1G>T p.X62_splice (on ENST00000605844 / NM_139215.3; = p.X59_splice on NM_003487.4) | Splice Site (SNP) | VAF 35/199 reads (18%) | called by muse, mutect2, varscan2
- TAS2R41 | c.283G>T p.A95S | Missense Mutation (SNP) | VAF 72/409 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- TBATA | c.892C>G p.Q298E | Missense Mutation (SNP) | VAF 27/212 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- TBC1D22B | c.131C>G p.S44* | Nonsense Mutation (SNP) | VAF 12/101 reads (12%) | called by muse, mutect2, varscan2
- TBC1D3B | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 30/702 reads (4%) | SIFT tolerated, low confidence (0.42); PolyPhen possibly damaging (0.533); called by muse, mutect2
- TCHP | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 10/200 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TCTEX1D2 | c.114G>T p.R38S | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TEAD2 | c.1139G>A p.C380Y | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TESK2 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.251); called by muse, mutect2
- TLR7 | c.998C>A p.A333D | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- TMC2 | c.2092C>G p.L698V | Missense Mutation (SNP) | VAF 56/672 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.213); called by muse, mutect2
- TMED4 | c.534+6T>G | Splice Region (SNP) | VAF 8/144 reads (6%) | called by muse, mutect2
- TMEM132B | c.2024A>T p.H675L | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.08); called by muse, mutect2
- TMEM132B | c.2346A>T p.K782N | Missense Mutation (SNP) | VAF 34/344 reads (10%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2
- TMEM138 | c.159C>G p.I53M | Missense Mutation (SNP) | VAF 12/137 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.157); called by muse, mutect2
- TMEM237 | c.103A>T p.K35* (on ENST00000409883 / NM_001044385.3; = p.K27* on NM_152388.4) | Nonsense Mutation (SNP) | VAF 20/177 reads (11%) | called by muse, mutect2, varscan2
- TMX4 | c.982G>T p.A328S | Missense Mutation (SNP) | VAF 26/291 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- TNN | c.3433G>C p.D1145H | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TOM1L2 | c.1001G>T p.G334V (on ENST00000379504 / NM_001350333.2; = p.G284V on NM_001033551.3) | Missense Mutation (SNP) | VAF 30/238 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TP53I13 | c.91G>T p.E31* | Nonsense Mutation (SNP) | VAF 69/570 reads (12%) | called by muse, mutect2, varscan2
- TPH1 | c.799G>T p.E267* | Nonsense Mutation (SNP) | VAF 29/228 reads (13%) | called by muse, mutect2, varscan2
- TRAJ9 | c.18C>G p.F6L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | called by muse, mutect2
- TRAPPC10 | c.2150G>T p.G717V | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2
- TRBC2 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 38/389 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRBV5-1 | c.249C>G p.F83L | Missense Mutation (SNP) | VAF 18/167 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- TREML2 | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 27/241 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TRIP12 | c.4334C>T p.S1445L | Missense Mutation (SNP) | VAF 4/45 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.025); called by muse, mutect2
- TRO | c.559G>T p.A187S | Missense Mutation (SNP) | VAF 67/227 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- TRPM5 | c.726G>T p.R242S | Missense Mutation (SNP) | VAF 5/81 reads (6%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2
- TTC38 | c.796-1G>T p.X266_splice | Splice Site (SNP) | VAF 45/272 reads (17%) | called by muse, mutect2, varscan2
- TTL | c.549G>C p.Q183H | Missense Mutation (SNP) | VAF 25/259 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TTLL1 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 39/206 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.451); called by muse, mutect2, varscan2
- TTLL7 | c.880G>T p.D294Y | Missense Mutation (SNP) | VAF 13/82 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- TTN | c.96052G>A p.V32018I (on ENST00000591111; = p.V24594I on NM_003319.4) | Missense Mutation (SNP) | VAF 18/135 reads (13%) | PolyPhen benign (0.329); called by muse, mutect2, varscan2
- TUBB8 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 44/613 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2
- TXNRD1 | c.1913C>T p.S638F (on ENST00000525566 / NM_001093771.3; = p.S540F on NM_003330.4) | Missense Mutation (SNP) | VAF 32/285 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- TXNRD3 | c.322C>G p.Q108E | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- TYR | c.1370C>G p.P457R | Missense Mutation (SNP) | VAF 14/237 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2
- UBXN10 | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 47/393 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- UNC79 | c.5216G>T p.S1739I (on ENST00000393151 / NM_001346218.2; = p.S1562I on NM_020818.5) | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); called by muse, mutect2
- UNC80 | c.5578G>T p.D1860Y | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- USP17L10 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 85/722 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- USP17L10 | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 58/1722 reads (3%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- USP17L13 | c.1306C>G p.R436G | Missense Mutation (SNP) | VAF 134/1204 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- USP36 | c.544G>T p.G182C | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VGLL1 | c.55A>T p.I19L | Missense Mutation (SNP) | VAF 23/132 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- VIPR2 | c.404G>T p.S135I | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- VN1R4 | c.602C>A p.S201Y | Missense Mutation (SNP) | VAF 32/345 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.169); called by muse, mutect2
- VWA3B | c.1360C>A p.H454N | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- VWF | c.8209G>T p.G2737* | Nonsense Mutation (SNP) | VAF 32/470 reads (7%) | called by muse, mutect2
- WDCP | c.2084C>T p.S695F | Missense Mutation (SNP) | VAF 23/250 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.078); called by muse, mutect2
- WDR72 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- WNK2 | c.3734del p.T1245Sfs*6 | Frame Shift Del (DEL) | VAF 26/119 reads (22%) | called by mutect2, pindel, varscan2
- WNT10A | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- WSCD2 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- WWC1 | c.3299G>T p.R1100L | Missense Mutation (SNP) | VAF 55/248 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- XIRP1 | c.3745C>A p.P1249T | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- YKT6 | c.386G>T p.R129I | Missense Mutation (SNP) | VAF 35/254 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- ZFHX4 | c.1717C>A p.H573N | Missense Mutation (SNP) | VAF 24/184 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFHX4 | c.5561C>A p.S1854Y | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.447); called by muse, mutect2
- ZNF257 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 42/254 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- ZNF385D | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF407 | c.2654A>T p.K885M | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2
- ZNF487 | c.228G>T p.M76I | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF521 | c.1378C>A p.H460N | Missense Mutation (SNP) | VAF 22/414 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF544 | c.234G>C p.E78D | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2
- ZNF551 | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 27/150 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.501); called by muse, mutect2, varscan2
- ZNF638 | c.5647G>A p.E1883K | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF679 | c.262G>T p.V88F | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.64); called by muse, mutect2
- ZSCAN12 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 41/394 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ACACB | c.4512G>T p.R1504= | Silent (SNP) | VAF 54/585 reads (9%) | called by muse, mutect2
- ACACB | c.4701G>T p.R1567= | Silent (SNP) | VAF 19/272 reads (7%) | called by muse, mutect2
- ACAN | c.5415C>T p.F1805= | Silent (SNP) | VAF 81/642 reads (13%) | catalogued as COSV61369399; called by muse, mutect2, varscan2
- ADO | c.669C>T p.Y223= | Silent (SNP) | VAF 20/409 reads (5%) | called by muse, mutect2
- AGBL4 | c.573G>T p.R191= | Silent (SNP) | VAF 14/129 reads (11%) | called by muse, varscan2
- AIP | c.705C>G p.L235= | Silent (SNP) | VAF 29/481 reads (6%) | catalogued as rs1464580715, COSV99069130, COSV99653659; ClinVar: likely benign; called by muse, mutect2
- AKNA | c.1719C>T p.F573= | Silent (SNP) | VAF 60/362 reads (17%) | called by muse, varscan2
- ALK | c.2574A>G p.P858= | Silent (SNP) | VAF 68/485 reads (14%) | catalogued as rs938866877; called by muse, mutect2, varscan2
- ALPK3 | c.3093G>C p.L1031= | Silent (SNP) | VAF 26/212 reads (12%) | catalogued as rs752722020, COSV51937470; called by muse, mutect2, varscan2
- ANKFN1 | c.3225G>A p.A1075= (on ENST00000653862; = p.A928= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 46/640 reads (7%) | catalogued as rs756457420; called by muse, mutect2
- AP2M1 | c.1020G>T p.G340= | Silent (SNP) | VAF 16/226 reads (7%) | called by muse, mutect2
- ASPHD2 | c.645G>T p.P215= | Silent (SNP) | VAF 34/327 reads (10%) | catalogued as COSV53218268; called by muse, mutect2, varscan2
- ATG2A | c.3783G>C p.S1261= | Silent (SNP) | VAF 26/161 reads (16%) | catalogued as rs764929953; called by muse, mutect2, varscan2
- ATN1 | c.393G>T p.T131= | Silent (SNP) | VAF 26/360 reads (7%) | catalogued as COSV63110953; called by muse, mutect2
- B3GALNT1 | c.84G>C p.L28= | Silent (SNP) | VAF 39/286 reads (14%) | catalogued as rs199813560, COSV100251886; called by muse, mutect2, varscan2
- BAG6 | c.1986G>T p.G662= (on ENST00000676571; = p.G615= on NM_080702.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 101/704 reads (14%) | called by muse, mutect2, varscan2
- BAK1 | c.528C>T p.G176= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2
- BBS1 | c.180C>G p.G60= | Silent (SNP) | VAF 52/434 reads (12%) | called by muse, mutect2, varscan2
- BCL2L1 | c.270G>A p.L90= | Silent (SNP) | VAF 29/259 reads (11%) | called by muse, mutect2, varscan2
- BEST3 | c.351C>T p.S117= | Silent (SNP) | VAF 27/443 reads (6%) | catalogued as rs779297098, COSV99876435; called by muse, mutect2
- C16orf90 | c.228C>G p.L76= (on ENST00000399645 / NM_001353385.2; = p.L67= on NM_001080524.2) | Silent (SNP) | VAF 40/236 reads (17%) | catalogued as rs762958884; called by muse, mutect2, varscan2
- C2orf68 | c.186C>A p.P62= | Silent (SNP) | VAF 29/440 reads (7%) | called by muse, mutect2
- CACNG6 | c.447G>T p.L149= | Silent (SNP) | VAF 34/290 reads (12%) | called by muse, mutect2, varscan2
- CAMTA1 | c.3624C>G p.P1208= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as COSV100345133; called by muse, mutect2, varscan2
- CCDC65 | c.168G>A p.L56= | Silent (SNP) | VAF 4/39 reads (10%) | catalogued as COSV57195356; called by muse, mutect2
- CCN1 | c.795G>A p.R265= | Silent (SNP) | VAF 50/520 reads (10%) | catalogued as rs1476465572; called by muse, mutect2
- CDC42BPG | c.759C>T p.Y253= | Silent (SNP) | VAF 60/792 reads (8%) | catalogued as rs770679398; called by muse, mutect2
- CELSR2 | c.7065C>T p.H2355= | Silent (SNP) | VAF 17/353 reads (5%) | called by muse, mutect2
- CHP2 | c.579G>T p.R193= | Silent (SNP) | VAF 15/157 reads (10%) | called by muse, mutect2
- CHRM2 | c.171C>A p.V57= | Silent (SNP) | VAF 81/557 reads (15%) | called by muse, mutect2, varscan2
- COL11A2 | c.1290C>A p.P430= (on ENST00000341947 / NM_080680.3; = p.P323= on NM_080679.2) | Silent (SNP) | VAF 32/241 reads (13%) | called by muse, mutect2, varscan2
- COL6A3 | c.7941A>G p.R2647= | Silent (SNP) | VAF 10/113 reads (9%) | called by muse, mutect2
- COL6A5 | c.1641C>G p.L547= | Silent (SNP) | VAF 38/324 reads (12%) | called by muse, mutect2, varscan2
- COL9A1 | c.1413A>T p.R471= | Silent (SNP) | VAF 53/384 reads (14%) | called by muse, mutect2, varscan2
- CPEB2 | c.672C>G p.L224= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- CSE1L | c.1587C>G p.L529= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs771282629, COSV53700539; called by muse, mutect2
- CSF1R | c.111G>A p.T37= | Silent (SNP) | VAF 59/460 reads (13%) | catalogued as rs762392545, COSV53838999, COSV99641856; called by muse, mutect2, varscan2
- CSPG4 | c.1260G>T p.G420= | Silent (SNP) | VAF 44/305 reads (14%) | called by muse, mutect2, varscan2
- CTTNBP2NL | c.747G>A p.L249= | Silent (SNP) | VAF 23/354 reads (6%) | called by muse, mutect2
- CYBB | c.1041G>A p.E347= | Silent (SNP) | VAF 52/253 reads (21%) | catalogued as rs782623269; called by muse, mutect2, varscan2
- CYP2U1 | c.81G>T p.L27= | Silent (SNP) | VAF 32/213 reads (15%) | called by muse, mutect2, varscan2
- DAAM2 | c.678G>C p.V226= | Silent (SNP) | VAF 40/440 reads (9%) | called by muse, mutect2
- DLG5 | c.702G>T p.L234= | Silent (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- DOCK7 | c.2844T>C p.S948= | Silent (SNP) | VAF 13/221 reads (6%) | called by muse, mutect2
- DPP6 | c.2571A>T p.T857= (on ENST00000377770 / NM_001364500.2; = p.T795= on NM_001936.5) | Silent (SNP) | VAF 24/169 reads (14%) | called by muse, mutect2, varscan2
- DSG1 | c.435C>T p.V145= | Silent (SNP) | VAF 20/416 reads (5%) | called by muse, mutect2
- DTL | c.1659G>A p.R553= | Silent (SNP) | VAF 31/248 reads (13%) | catalogued as rs1180123010; called by muse, mutect2, varscan2
- EBF1 | c.519A>G p.R173= | Silent (SNP) | VAF 60/262 reads (23%) | called by muse, mutect2, varscan2
245 further variants in this file (0 protein-altering or splice-affecting, 145 silent, 100 other) are not listed here.
